Somatic mutation profile of tumor specimen TCGA-KR-A7K8-01A (aliquot TCGA-KR-A7K8-01A-11D-A33K-10) from TCGA case TCGA-KR-A7K8, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 57.3 years (20,914 days).
Specimen TCGA-KR-A7K8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69a83a69-8a76-4f5d-9452-75fb6c439ea7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KR-A7K8-10A (Blood Derived Normal), aliquot TCGA-KR-A7K8-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa3da97e-1714-453e-aae7-bc87593bf1f8

The open-access MAF lists 55 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Nonsense Mutation 6, Frame Shift Ins 2, Intron 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT1 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs753448518, COSV58574333; called by muse, varscan2
- ACOT2 | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1173801451, COSV53150772; called by muse, mutect2
- ADRB2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60005441; called by muse, mutect2, varscan2
- BAG6 | c.2139G>T p.Q713H (on ENST00000676571; = p.Q666H on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as COSV52990165; called by muse, mutect2
- CCDC137 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 25/121 reads (21%) | catalogued as rs781772780, COSV61303269; called by muse, mutect2, varscan2
- CCDC50 | c.1417T>G p.S473A (on ENST00000392455 / NM_178335.3; = p.S297A on NM_174908.4) | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.088); catalogued as COSV66667866; called by muse, mutect2
- CHCHD4 | c.44T>C p.V15A (on ENST00000396914 / NM_001098502.2; = p.V28A on NM_144636.3) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.607); catalogued as rs1559356610, COSV55499840; called by muse, mutect2, varscan2
- CLEC1A | c.392-2A>G p.X131_splice | Splice Site (SNP) | VAF 6/116 reads (5%) | catalogued as rs1223867794, COSV59531887; called by muse, mutect2
- CT45A10 | c.347C>G p.P116R | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV100867553, COSV65921191; called by muse, mutect2, varscan2
- DNAH5 | c.9286C>T p.R3096* | Nonsense Mutation (SNP) | VAF 26/252 reads (10%) | catalogued as rs868444911, CM147994, COSV54213734; called by muse, mutect2
- DNAH7 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56762897; called by muse, mutect2
- ERG | c.1275G>A p.M425I (on ENST00000398919 / NM_001243428.1; = p.M401I on NM_004449.4) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55731462; called by muse, mutect2, varscan2
- FBH1 | c.136A>T p.R46* (on ENST00000362091 / NM_178150.3; = p.R97* on NM_032807.4) | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV62982431; called by muse, mutect2, varscan2
- FYCO1 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV56115654; called by muse, mutect2, varscan2
- GALNT12 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV66662641; called by muse, mutect2, varscan2
- GLRA3 | c.1388A>C p.Q463P | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.84); catalogued as rs1260056462, COSV56861151; called by muse, mutect2, varscan2
- GSTA2 | c.331T>G p.F111V | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV72414895; called by muse, mutect2
- IGHV3-53 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.35); catalogued as rs1555545015; called by muse, mutect2
- IGHV6-1 | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781784345; called by muse, mutect2, varscan2
- IQGAP2 | c.1468C>T p.H490Y | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56970574; called by muse, mutect2, varscan2
- KMT5A | c.542T>G p.L181R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV100389674, COSV57863049; called by muse, mutect2, varscan2
- PENK | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1216096657, COSV59241133; called by muse, mutect2, varscan2
- PHACTR4 | c.1572C>G p.Y524* (on ENST00000373839 / NM_001350159.2; = p.Y534* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 14/399 reads (4%) | catalogued as COSV100868435; called by muse, mutect2
- PMP2 | c.103A>G p.N35D | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.097); catalogued as COSV56266985; called by muse, mutect2, varscan2
- PSMA8 | c.753dup p.S252Ifs*16 | Frame Shift Ins (INS) | VAF 15/93 reads (16%) | catalogued as rs777177735; called by mutect2, pindel, varscan2
- RHBDD1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV58126481; called by muse, mutect2, varscan2
- RNF11 | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54376359; called by muse, varscan2
- RTN4R | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs748655075, CM086907, COSV50381103; called by muse, mutect2, varscan2
- SORBS1 | c.58A>T p.S20C | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.759); catalogued as COSV53356995; called by muse, mutect2
- SPATA1 | c.571dup p.S191Kfs*12 | Frame Shift Ins (INS) | VAF 42/390 reads (11%) | catalogued as rs1159192656; called by mutect2, pindel, varscan2
- TAAR2 | c.560G>T p.G187V (on ENST00000367931 / NM_001033080.1; = p.G142V on NM_014626.3) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51578414, COSV51579062; called by muse, mutect2, varscan2
- TEX45 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64463113; called by muse, mutect2, varscan2
- THOC5 | c.1829A>T p.K610M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV63798540; called by muse, mutect2, varscan2
- TMEM150B | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1033483663, COSV58593651; called by muse, mutect2, varscan2
- TMPRSS7 | c.1663C>T p.Q555* (on ENST00000452346; = p.Q429* on NM_001042575.2) | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | catalogued as COSV69980491; called by muse, mutect2, varscan2
- TSC1 | c.1829T>C p.V610A | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV53766588; called by muse, mutect2
- TSSC4 | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV50151097; called by muse, mutect2, varscan2
- ZBTB2 | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV57312423; called by muse, mutect2, varscan2
- ZNF133 | c.1271C>A p.T424N (on ENST00000316358 / NM_001352454.2; = p.T423N on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as COSV60366913; called by muse, mutect2, varscan2
- ZNF366 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.745); catalogued as rs773571362, COSV59214236; called by muse, mutect2, varscan2
- ACAN | c.2103C>A p.I701= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV61359855; called by muse, mutect2, varscan2
- BORCS5 | c.123C>T p.S41= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV53802136; called by muse, mutect2
- DGKD | c.333C>A p.V111= (on ENST00000264057 / NM_152879.3; = p.V67= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV51043828, COSV51080296; called by muse, mutect2
- H3C3 | c.48T>A p.A16= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs777821287, COSV63550938; called by muse, mutect2
- LHFPL3 | c.222G>T p.L74= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV67810611; called by muse, mutect2, varscan2
- LRRK1 | c.2751G>A p.R917= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1008792565, COSV52609940; called by muse, mutect2, varscan2
- MYH9 | c.2247C>A p.L749= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV53385608, COSV99337799; called by muse, mutect2, varscan2
- PPP1R14D | c.21T>G p.A7= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV54544025; called by muse, mutect2, varscan2
- RUNX3 | c.750C>T p.R250= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs1459416077, COSV58243617; called by muse, mutect2, varscan2
- WHAMM | c.696T>A p.V232= | Silent (SNP) | VAF 30/188 reads (16%) | catalogued as COSV54496250; called by muse, mutect2, varscan2
- ZNF311 | c.1219A>C p.R407= | Silent (SNP) | VAF 13/287 reads (5%) | catalogued as COSV65853082; called by muse, mutect2
- ZNF33A | c.516T>C p.C172= (on ENST00000458705 / NM_006974.3; = p.C173= on NM_006954.2) | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV56724709, COSV56727933; called by muse, mutect2, varscan2
- NIN | chr14:50723610 C>A | 3'Flank (SNP) | VAF 15/107 reads (14%) | catalogued as COSV55388937; called by muse, mutect2, varscan2
- TTN | c.10360+3374A>T | Intron (SNP) | VAF 8/150 reads (5%) | catalogued as COSV60025443; called by muse, mutect2
- TTN | c.10360+3373T>G | Intron (SNP) | VAF 7/147 reads (5%) | catalogued as COSV60025454; called by muse, mutect2
